Gene-level copy-number profile of tumor specimen TCGA-2G-AAHF-01A from TCGA case TCGA-2G-AAHF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 40.6 years (14,825 days).
Specimen TCGA-2G-AAHF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4299b0ae-f397-4589-877a-5fcc65144253.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/a1fd3920-8d83-42da-a70d-696c9c477859

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,147; copy number 2: 14,200; copy number 3: 23,805; copy number 4: 11,086; copy number 5: 7,475; copy number 6: 422; copy number 7: 98; copy number 9: 659; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,131,306–41,355,538, 9 genes (within-gene range 0–2): CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6.
- chr9:64,810,865–64,889,063, 4 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 762 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:61,143,656–68,997,709, 101 genes, copy number 7–12 (broad region; genes not listed).
- chr4:69,051,363–69,112,987, 2 genes, copy number 7 (within-gene range 6–7): UGT2B7, AC111000.2.
- chr12:66,767–26,299,290, 659 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
